Somatic mutation profile of tumor specimen TCGA-G3-A3CG-01A (aliquot TCGA-G3-A3CG-01A-11D-A20W-10) from TCGA case TCGA-G3-A3CG, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 80.6 years (29,432 days).
Specimen TCGA-G3-A3CG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 18a60613-3b88-45f3-b76a-f65d5c116faf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G3-A3CG-10A (Blood Derived Normal), aliquot TCGA-G3-A3CG-10A-01D-A20W-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96a169e8-70fe-4af0-ae4f-3da09e12d19b

The open-access MAF lists 118 somatic variants for this specimen: 87 protein-altering or splice-affecting, 29 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 29, Nonsense Mutation 9, Splice Region 6, Frame Shift Del 4, In Frame Del 2, Intron 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.7103C>A p.A2368D | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.283); catalogued as COSV101446894, COSV101447082; called by muse, mutect2, varscan2
- ADAD1 | c.932C>T p.S311F | Missense Mutation (SNP) | VAF 34/260 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV56641086, COSV56641429, COSV99636010; called by muse, mutect2, varscan2
- AFAP1L1 | c.1556C>T p.A519V | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs1413854340, COSV57044407, COSV57044996; called by muse, mutect2, varscan2
- AKR1C2 | c.18G>T p.Q6H | Missense Mutation (SNP) | VAF 66/199 reads (33%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.001); catalogued as COSV101060502; called by muse, mutect2, varscan2
- ARHGAP1 | c.340C>G p.Q114E | Missense Mutation (SNP) | VAF 35/174 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as COSV100357998; called by muse, mutect2, varscan2
- ARHGAP5 | c.290A>T p.E97V | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100565574; called by muse, mutect2, varscan2
- ATP8B2 | c.3174G>T p.W1058C (on ENST00000672630; = p.W1025C on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 144/474 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100528139; called by muse, mutect2, varscan2
- CD58 | c.232A>T p.K78* | Nonsense Mutation (SNP) | VAF 62/169 reads (37%) | catalogued as COSV101043944, COSV65664629; called by muse, mutect2, varscan2
- CDC37L1 | c.481A>C p.K161Q | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as COSV101116623; called by muse, mutect2, varscan2
- CNOT1 | c.2146G>T p.G716* | Nonsense Mutation (SNP) | VAF 15/47 reads (32%) | catalogued as COSV100409846; called by muse, mutect2
- CNOT6 | c.95C>G p.A32G | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.045); catalogued as COSV99993735; called by muse, mutect2, varscan2
- COL22A1 | c.227G>T p.R76L | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57359587, COSV57365604; called by muse, mutect2, varscan2
- COL28A1 | c.2509A>C p.I837L | Missense Mutation (SNP) | VAF 50/238 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.133); catalogued as COSV101258810; called by muse, mutect2, varscan2
- CSMD1 | c.3478G>T p.V1160L (on ENST00000520002; = p.V1159L on NM_033225.6) | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as COSV100151353; called by muse, mutect2, varscan2
- CXCL5 | c.77T>C p.L26P | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99932923; called by muse, mutect2, varscan2
- DDIAS | c.2081C>T p.T694I | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV100231333; called by muse, mutect2, varscan2
- DISP1 | c.4465G>C p.V1489L | Missense Mutation (SNP) | VAF 38/260 reads (15%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV99451640; called by muse, mutect2, varscan2
- DLGAP1 | c.1277C>A p.A426E | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as COSV100232664; called by muse, mutect2, varscan2
- DNAH2 | c.3838G>T p.D1280Y | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV101209502; called by muse, mutect2
- DNAJC22 | c.653T>A p.F218Y | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as COSV101222583; called by muse, mutect2
- DNM2 | c.1307T>G p.I436S | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.026); catalogued as COSV100117639; called by muse, mutect2, varscan2
- DYSF | c.106A>T p.K36* | Nonsense Mutation (SNP) | VAF 79/208 reads (38%) | catalogued as COSV99249204; called by muse, mutect2, varscan2
- EHD2 | c.98T>A p.L33Q | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99622102; called by muse, mutect2, varscan2
- EIF3B | c.999G>A p.A333= | Splice Region (SNP) | VAF 19/48 reads (40%) | catalogued as COSV100703791; called by muse, mutect2, varscan2
- ERF | c.391A>G p.S131G | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.278); catalogued as COSV99724777; called by muse, mutect2, varscan2
- FBXO38 | c.939C>A p.Y313* | Nonsense Mutation (SNP) | VAF 62/249 reads (25%) | catalogued as COSV99693735; called by muse, mutect2, varscan2
- FCRL5 | c.560A>G p.E187G | Missense Mutation (SNP) | VAF 56/103 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV100709138; called by muse, mutect2, varscan2
- GATB | c.1472A>T p.Q491L | Missense Mutation (SNP) | VAF 37/201 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as COSV99859178; called by muse, mutect2, varscan2
- H2AC21 | c.169G>T p.E57* | Nonsense Mutation (SNP) | VAF 69/316 reads (22%) | catalogued as COSV100480058, COSV58613229; called by muse, mutect2, varscan2
- HDAC6 | c.107A>G p.K36R | Missense Mutation (SNP) | VAF 54/82 reads (66%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.985); catalogued as COSV100491099; called by muse, mutect2, varscan2
- HECTD4 | c.11466C>T p.V3822= | Splice Region (SNP) | VAF 32/130 reads (25%) | catalogued as COSV101108093; called by muse, mutect2, varscan2
- HELZ | c.833A>T p.H278L | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.054); catalogued as COSV100698926; called by muse, mutect2, varscan2
- ITPR2 | c.5207A>T p.D1736V | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.878); catalogued as COSV101190085; called by muse, mutect2, varscan2
- KCNA10 | c.1124T>A p.L375* | Nonsense Mutation (SNP) | VAF 27/121 reads (22%) | catalogued as COSV100871460; called by muse, mutect2, varscan2
- KCNQ4 | c.532+2T>C p.X178_splice | Splice Site (SNP) | VAF 29/78 reads (37%) | catalogued as COSV100714384; called by muse, mutect2, varscan2
- KIF6 | c.1287G>A p.K429= | Splice Region (SNP) | VAF 20/51 reads (39%) | catalogued as COSV99759822; called by muse, mutect2, varscan2
- LAMB2 | c.1178_1180del p.F393del | In Frame Del (DEL) | VAF 32/131 reads (24%) | catalogued as rs905762968; called by pindel, varscan2
- LRRC8A | c.604A>G p.S202G | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.323); catalogued as COSV99396775; called by muse, mutect2, varscan2
- MAPT | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.038); catalogued as rs771618879, COSV99290976; called by muse, mutect2, varscan2
- MCMBP | c.1622C>G p.S541* | Nonsense Mutation (SNP) | VAF 24/78 reads (31%) | catalogued as COSV100750136; called by muse, mutect2, varscan2
- MEGF6 | c.3307C>T p.R1103C | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.701); catalogued as rs1334499663, COSV53896509; called by muse, mutect2
- MLH3 | c.2402_2403del p.S801* | Frame Shift Del (DEL) | VAF 18/116 reads (16%) | catalogued as rs748217287; called by pindel, varscan2
- MMP3 | c.401T>A p.V134D | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100242924; called by muse, mutect2, varscan2
- MYO9A | c.6895C>T p.R2299W | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs371514628; called by muse, mutect2, varscan2
- MYT1L | c.2171T>G p.M724R | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.663); catalogued as COSV101221057; called by muse, mutect2
- NCOR1 | c.7137C>G p.G2379= | Splice Region (SNP) | VAF 24/47 reads (51%) | catalogued as COSV99251131; called by muse, mutect2, varscan2
- NKAP | c.1113C>A p.N371K | Missense Mutation (SNP) | VAF 71/90 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100538368; called by muse, mutect2, varscan2
- NMUR2 | c.268T>A p.S90T | Missense Mutation (SNP) | VAF 53/103 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99677086; called by muse, mutect2, varscan2
- NPHS2 | c.776A>T p.K259I | Missense Mutation (SNP) | VAF 13/412 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV100858193; called by muse, mutect2
- NRBP1 | c.135A>T p.E45D | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV99275170; called by muse, mutect2, varscan2
- OR8D2 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV62488416; called by muse, mutect2, varscan2
- PCDHB10 | c.836A>G p.Y279C | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99504710; called by muse, mutect2
- PLEKHG4B | c.1066T>A p.C356S (on ENST00000283426; = p.C712S on NM_052909.5) | Missense Mutation (SNP) | VAF 64/151 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99360761; called by muse, mutect2, varscan2
- PLG | c.1801A>C p.R601= | Splice Region (SNP) | VAF 40/53 reads (75%) | catalogued as COSV100369422; called by muse, mutect2, varscan2
- PPP6R2 | c.560A>G p.N187S | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs775042064, COSV99324543; called by muse, mutect2, varscan2
- PRDM15 | c.3379G>A p.V1127I | Missense Mutation (SNP) | VAF 100/162 reads (62%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs777355181, COSV99520573; called by muse, varscan2
- PTCD1 | c.1786G>T p.A596S | Missense Mutation (SNP) | VAF 122/279 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.094); catalogued as COSV99464216; called by muse, mutect2, varscan2
- PXDNL | c.2869G>T p.G957W | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62478360; called by muse, mutect2, varscan2
- RCHY1 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 61/137 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as COSV100185921; called by muse, mutect2, varscan2
- RPL15 | c.181A>G p.I61V | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.045); catalogued as COSV100323264; called by muse, mutect2, varscan2
- SCPEP1 | c.127G>A p.V43M | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751679074, COSV99227943; called by muse, mutect2, varscan2
- SLC27A4 | c.65G>C p.W22S | Missense Mutation (SNP) | VAF 147/306 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100056631; called by muse, mutect2, varscan2
- SLC4A8 | c.1402A>C p.S468R | Missense Mutation (SNP) | VAF 29/301 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100177248; called by muse, mutect2
- SPTBN1 | c.2983C>T p.Q995* | Nonsense Mutation (SNP) | VAF 39/115 reads (34%) | catalogued as COSV100442053; called by muse, mutect2, varscan2
- SPTSSA | c.39G>A p.M13I | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1419244851, COSV99987832; called by muse, mutect2, varscan2
- TAOK2 | c.3259C>T p.R1087W | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs1031649698, COSV54230303; called by muse, mutect2, varscan2
- TARS2 | c.1555C>G p.L519V | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100945949, COSV100946040; called by muse, mutect2, varscan2
- TARS3 | c.1639A>T p.T547S | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as COSV100254857, COSV60109235; called by muse, mutect2, varscan2
- TDP1 | c.619G>T p.D207Y | Missense Mutation (SNP) | VAF 77/176 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100187995; called by muse, mutect2, varscan2
- TENM4 | c.2425A>T p.R809* | Nonsense Mutation (SNP) | VAF 32/164 reads (20%) | catalogued as COSV99576823; called by muse, mutect2, varscan2
- TKTL2 | c.1604T>A p.V535D | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99761598; called by muse, mutect2, varscan2
- TMEM254 | c.40A>C p.S14R | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as rs1000428633, COSV100953579; called by muse, mutect2, varscan2
- TNR | c.1962A>G p.T654= | Splice Region (SNP) | VAF 23/157 reads (15%) | catalogued as rs1387114956, COSV99690625; called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.2374G>A p.D792N | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.832); catalogued as rs1424480351, COSV100709126; called by muse, mutect2
- TTLL11 | c.106G>T p.A36S | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.038); catalogued as COSV100389072; called by muse, mutect2, varscan2
- UBE2K | c.165A>T p.R55S | Missense Mutation (SNP) | VAF 67/154 reads (44%) | SIFT tolerated (0.6); PolyPhen benign (0.019); catalogued as COSV99787308; called by muse, mutect2, varscan2
- UBR4 | c.9431A>G p.Y3144C | Missense Mutation (SNP) | VAF 59/196 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV100921369; called by muse, mutect2, varscan2
- UGGT2 | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV100942616; called by muse, mutect2, varscan2
- UPP1 | c.752C>T p.S251F | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100080819; called by muse, mutect2, varscan2
- USP22 | c.1453C>T p.R485W | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as rs370939634; called by muse, mutect2, varscan2
- ZNF684 | c.337A>G p.M113V | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1369205101, COSV101016087; called by muse, mutect2, varscan2
- ZW10 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs140270550; called by muse, mutect2, varscan2
- ARID1A | c.5042_5065del p.L1681_D1689delinsH | In Frame Del (DEL) | VAF 21/163 reads (13%) | called by mutect2, pindel*
- KIFC2 | c.1491_1492del p.P498* | Frame Shift Del (DEL) | VAF 30/121 reads (25%) | called by mutect2, pindel, varscan2
- NAGLU | c.871A>T p.I291F | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2
- NCOR1 | c.4722del p.H1575Tfs*40 | Frame Shift Del (DEL) | VAF 16/43 reads (37%) | called by mutect2, pindel, varscan2
- PLEKHN1 | c.1883_1892del p.R628Pfs*55 (on ENST00000379409; = p.R576Pfs*55 on NM_032129.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 20/64 reads (31%) | called by mutect2, pindel, varscan2
- ACADM | c.168C>T p.A56= | Silent (SNP) | VAF 32/114 reads (28%) | catalogued as COSV100897727; called by muse, mutect2, varscan2
- ADAMTS12 | c.753G>T p.L251= | Silent (SNP) | VAF 65/117 reads (56%) | catalogued as COSV100711410; called by muse, mutect2, varscan2
- ADD1 | c.1200G>T p.L400= | Silent (SNP) | VAF 37/171 reads (22%) | catalogued as COSV53272888, COSV99296743; called by muse, mutect2, varscan2
- AKAP13 | c.2673C>T p.D891= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as COSV63465660; called by muse, mutect2, varscan2
- ASGR1 | c.378C>T p.H126= | Silent (SNP) | VAF 85/244 reads (35%) | catalogued as rs768720174, COSV99352582; called by muse, mutect2, varscan2
- ATL3 | c.1416G>A p.L472= | Silent (SNP) | VAF 42/167 reads (25%) | catalogued as COSV100219943; called by muse, mutect2, varscan2
- ATXN2 | c.2673A>G p.A891= (on ENST00000550104; = p.A731= on NM_002973.4) | Silent (SNP) | VAF 48/165 reads (29%) | catalogued as rs138912353, COSV66484269, COSV66486760; called by muse, mutect2, varscan2
- BRINP3 | c.2244G>A p.A748= | Silent (SNP) | VAF 22/177 reads (12%) | catalogued as rs562180986, COSV66514032; called by muse, mutect2, varscan2
- CLPTM1 | c.639A>G p.T213= | Silent (SNP) | VAF 30/67 reads (45%) | catalogued as COSV100493879; called by muse, mutect2, varscan2
- EPS8L1 | c.714C>A p.A238= (on ENST00000201647 / NM_133180.3; = p.A111= on NM_017729.3) | Silent (SNP) | VAF 33/83 reads (40%) | catalogued as COSV99136759; called by muse, mutect2, varscan2
- FAM111B | c.1488G>A p.V496= | Silent (SNP) | VAF 51/213 reads (24%) | catalogued as COSV100639330; called by muse, mutect2, varscan2
- FMO3 | c.168A>G p.K56= | Silent (SNP) | VAF 139/262 reads (53%) | catalogued as COSV63008863; called by muse, mutect2, varscan2
- KATNAL2 | c.1449C>T p.I483= (on ENST00000356157 / NM_001353899.1; = p.I411= on NM_031303.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV99797342; called by muse, mutect2, varscan2
- KRT26 | c.916T>C p.L306= | Silent (SNP) | VAF 32/414 reads (8%) | catalogued as rs889629123, COSV100156574; called by muse, mutect2
- MDM2 | c.132A>G p.L44= | Silent (SNP) | VAF 4/64 reads (6%) | catalogued as COSV50705290; called by muse, mutect2
- MIDEAS | c.1863T>G p.P621= | Silent (SNP) | VAF 52/109 reads (48%) | catalogued as COSV99679105; called by muse, mutect2, varscan2
- NCAPD3 | c.1533C>T p.S511= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV101599381; called by muse, mutect2
- OR2T33 | c.180C>A p.L60= | Silent (SNP) | VAF 413/862 reads (48%) | catalogued as COSV100532169, COSV58818226; called by muse, varscan2
- OR5H1 | c.795G>A p.P265= | Silent (SNP) | VAF 49/187 reads (26%) | catalogued as rs138973744; called by muse, mutect2, varscan2
- PCLO | c.7029A>G p.P2343= | Silent (SNP) | VAF 48/177 reads (27%) | catalogued as COSV100435014; called by muse, mutect2, varscan2
- PLEKHG3 | c.1788C>T p.A596= (on ENST00000394691; = p.A652= on NM_001308147.2) | Silent (SNP) | VAF 30/59 reads (51%) | catalogued as rs910470085, COSV99906868; called by muse, mutect2, varscan2
- PLIN4 | c.3336G>A p.G1112= (on ENST00000301286; = p.G1127= on NM_001367868.2) | Silent (SNP) | VAF 24/81 reads (30%) | catalogued as COSV100013738; called by muse, mutect2, varscan2
- PRSS16 | c.1098T>C p.S366= | Silent (SNP) | VAF 77/199 reads (39%) | catalogued as COSV100041862; called by muse, mutect2, varscan2
- SMC4 | c.2814A>G p.Q938= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as COSV100557538; called by muse, mutect2, varscan2
- STARD6 | c.81T>G p.V27= | Silent (SNP) | VAF 51/152 reads (34%) | catalogued as COSV100266645; called by muse, mutect2, varscan2
- SZT2 | c.273T>G p.A91= | Silent (SNP) | VAF 37/112 reads (33%) | catalogued as COSV100161804; called by muse, mutect2, varscan2
- TIGIT | c.474C>A p.I158= | Silent (SNP) | VAF 5/73 reads (7%) | catalogued as COSV67328725, COSV67328815; called by muse, mutect2
- TRIM46 | c.291C>A p.P97= | Silent (SNP) | VAF 27/71 reads (38%) | catalogued as COSV99826028; called by muse, mutect2, varscan2
- ZMYND12 | c.312C>T p.H104= | Silent (SNP) | VAF 46/143 reads (32%) | catalogued as rs1397568510, COSV100999870; called by muse, mutect2, varscan2
- GON4L | c.4473+26T>C | Intron (SNP) | VAF 61/353 reads (17%) | catalogued as COSV99675155; called by muse, mutect2, varscan2
- NME4 | c.91+585G>T | Intron (SNP) | VAF 10/43 reads (23%) | catalogued as COSV99556814; called by muse, mutect2, varscan2
